Somatic mutation profile of tumor specimen ALCH-B4UL-TTP1-A (aliquot ALCH-B4UL-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4UL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.6 years (26,520 days).
Specimen ALCH-B4UL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d3e9a2e-6c81-4e4b-923b-a744dcc44aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4UL-NB1-A (Blood Derived Normal), aliquot ALCH-B4UL-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6362d2-45a3-4ad4-8b5e-a99c767d874b

The open-access MAF lists 80 somatic variants for this specimen: 59 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 12, Intron 4, Nonsense Mutation 4, 5'UTR 3, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 158/549 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 26/215 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV57857225, COSV57893995; called by muse, mutect2, varscan2
- ANKRD34C | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV69855471; called by muse, mutect2, varscan2
- CARD11 | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs1455337069, COSV99052497; called by muse, mutect2, varscan2
- CCL1 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV56774669, COSV56775699; called by muse, varscan2
- DEAF1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1219925185; called by muse, varscan2
- DSCAM | c.5350G>A p.D1784N | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs940476276, COSV68033878; called by muse, mutect2, varscan2
- FMN1 | c.3653G>A p.R1218Q (on ENST00000616417 / NM_001277313.2; = p.R995Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1364762932, COSV57928129; called by muse, mutect2, varscan2
- GDF2 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as CM138626; called by muse, mutect2, varscan2
- GREB1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs375384889; called by muse, mutect2, varscan2
- LOXHD1 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs769584753, COSV56066863; called by muse, mutect2
- MCF2L2 | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61057748; called by muse, mutect2, varscan2
- MYO1E | c.2627+1G>T p.X876_splice | Splice Site (SNP) | VAF 45/290 reads (16%) | catalogued as COSV55688122; called by muse, mutect2, varscan2
- OR2AT4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs369166223, COSV59406783; called by muse, mutect2
- PKN2 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs1358475710; called by muse, mutect2
- PRDM9 | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV57010866; called by muse, mutect2
- SRGAP2B | c.380G>C p.R127P | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV101523380; called by muse, mutect2, varscan2
- TBX19 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 48/550 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs764256599, COSV100892332; called by muse, mutect2
- ZSCAN1 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.25); catalogued as COSV56603403; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP25 | c.204T>A p.F68L (on ENST00000409202 / NM_001007231.3; = p.F61L on NM_014882.3) | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- ASB3 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 29/224 reads (13%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ASCC3 | c.6461G>T p.R2154M | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- ATP4A | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | called by muse, mutect2, varscan2
- BIRC6 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BMPR1B | c.1390A>T p.R464W | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.2908_2914+4del p.X970_splice | Splice Site (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel
- CCSER1 | c.1109A>C p.D370A | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2
- CHKA | c.455_462del p.L152* | Frame Shift Del (DEL) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- CLDN17 | c.419C>G p.T140R | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CNOT1 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 83/366 reads (23%) | called by muse, mutect2, varscan2
- COG8 | c.304_305insCAGG p.R102Pfs*43 | Frame Shift Ins (INS) | VAF 41/160 reads (26%) | called by mutect2, pindel, varscan2
- CSH2 | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- DENND10 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2
- DNAH14 | c.6751G>A p.E2251K (on ENST00000445597; = p.E2904K on NM_001367479.1) | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- EPHB4 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- FGB | c.381del p.D128Mfs*3 | Frame Shift Del (DEL) | VAF 48/264 reads (18%) | called by mutect2, pindel*, varscan2
- GRID1 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13B | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN3 | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LTBP4 | c.4390G>T p.A1464S (on ENST00000308370 / NM_001042544.1; = p.A1427S on NM_003573.2) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MGAM2 | c.5369T>C p.I1790T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- PARP9 | c.2236del p.A746Qfs*13 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel
- PCDHB1 | c.2317C>A p.R773S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PDE1C | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 57/431 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PHRF1 | c.1979G>A p.S660N (on ENST00000264555 / NM_001286581.2; = p.S659N on NM_020901.4) | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- POLR3E | c.1637A>T p.N546I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRDM13 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PRR32 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RBM10 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- RELN | c.6443G>A p.C2148Y | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SHCBP1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLFN14 | c.1250A>T p.H417L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- SOX7 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ST18 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- SYNJ2 | c.3197C>T p.P1066L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- TENM4 | c.5096G>C p.S1699T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF423 | c.2267A>T p.K756M (on ENST00000563137 / NM_001379286.1; = p.K748M on NM_015069.4) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALLC | c.222C>A p.G74= | Silent (SNP) | VAF 28/196 reads (14%) | called by muse, mutect2, varscan2
- GPR162 | c.258C>T p.N86= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1377735189, COSV50592391; called by muse, mutect2
- LRRC70 | c.1674A>G p.A558= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- LTBP1 | c.2928G>A p.V976= (on ENST00000404816 / NM_206943.4; = p.V650= on NM_000627.4) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs757434501; called by muse, mutect2, varscan2
- MXRA5 | c.7797C>A p.G2599= | Silent (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- OR51B5 | c.657A>T p.I219= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV56175439; called by muse, mutect2
- OR6F1 | c.342C>A p.L114= | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- SLC38A10 | c.1335G>T p.P445= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV99917858; called by muse, mutect2, varscan2
- SP100 | c.1746G>A p.L582= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV50979985; called by muse, mutect2, varscan2
- THRB | c.699C>T p.N233= | Silent (SNP) | VAF 67/525 reads (13%) | catalogued as rs759545673; called by muse, mutect2, varscan2
- TMPRSS5 | c.924C>T p.D308= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as rs940816039; called by muse, mutect2, varscan2
- ZBED6CL | c.342A>G p.E114= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV59604922; called by muse, mutect2, varscan2
- AC006305.1 | n.950G>C | RNA (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- CHMP6 | chr17:81004683 G>C | 3'Flank (SNP) | VAF 4/36 reads (11%) | catalogued as rs1344853804; called by muse, mutect2
- CRHBP | c.82-38C>A | Intron (SNP) | VAF 36/280 reads (13%) | called by muse, mutect2, varscan2
- GABRA6 | c.673+32C>T | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- KPNA6 | c.-3G>T | 5'UTR (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- TP53TG5 | c.-12C>T | 5'UTR (SNP) | VAF 10/158 reads (6%) | catalogued as COSV101022366, COSV65577819; called by muse, mutect2
- UBR2 | c.1281+92G>T | Intron (SNP) | VAF 52/333 reads (16%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23354G>A | Intron (SNP) | VAF 36/219 reads (16%) | catalogued as rs555741522, COSV59386222; called by muse, mutect2, varscan2
- WTAP | c.-456T>C | 5'UTR (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
